Gene-level copy-number profile of tumor specimen MP2PRT-PASSDM-TMP1-A from MP2PRT case MP2PRT-PASSDM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,424 days).
Specimen MP2PRT-PASSDM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 61120952-d06f-4acd-93bb-0b59bad2630b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASSDM-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,753 have no estimate.
https://portal.gdc.cancer.gov/files/fab53ef0-0615-46f3-a260-db1427e2cabe

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 2: 648; copy number 3: 244; copy number 4: 32,780; copy number 5: 1,367; copy number 6: 21,026; copy number 7: 95; copy number 8: 2,088; copy number 9: 186; copy number 10: 32; copy number 11: 211; copy number 12: 49; copy number 13: 23; copy number 16: 46; copy number 17: 22.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,170,550–7,200,857, 3 genes: SNRPCP15, RPS3AP33, AF228730.1.
- chr14:105,851,705–106,108,464, 49 genes (within-gene range 0–4): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–2): IGHVIII-16-1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 569 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,537,184–68,616,137, 3 genes, copy number 9: UGT2B17, AC147055.2, AC147055.4.
- chr4:68,646,597–68,670,652, 1 gene, copy number 9: UGT2B15.
- chr7:38,239,580–38,249,572, 1 gene, copy number 9: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 9: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr8:12,393,209–12,665,588, 8 genes, copy number 9 (within-gene range 6–9): DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1.
- chr14:18,333,726–22,482,959, 263 genes, copy number 10–17 (within-gene range 5–22) (broad region; genes not listed).
- chr14:22,455,249–24,657,774, 199 genes, copy number 9–17 (within-gene range 5–17) (broad region; genes not listed).
- chr14:34,485,979–36,679,362, 71 genes, copy number 10–12 (within-gene range 8–12) (broad region; genes not listed).
- chr18:45,034–94,330, 5 genes, copy number 9: AP001005.1, TUBB8B, AP001005.3, IL9RP4, AP001005.2.
- chr18:80,157,232–80,247,514, 1 gene, copy number 10 (within-gene range 8–10): PARD6G.
- chr18:80,183,680–80,202,992, 1 gene, copy number 10: AC139100.1.
- chr21:8,603,547–8,603,984, 1 gene, copy number 12: RPSAP68.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
